Surgical pathology report (de-identified scan), TCGA case TCGA-19-1789, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-1789-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS

A. RIGHT OCCIPITAL NEOPLASM, BIOPSY:
-- INFILTRATING GLIOMA.

B. RIGHT OCCIPITAL NEOPLASM, BIOPSY NUMBER TWO:
-- MALIGNANT ASTROCYTOMA.

C. SPECIMEN LABELED SECOND PERMANENT CORE:
-- MALIGNANT ASTROCYTOMA.

D. SPECIMEN LABELED THREE PERMANENT EDGE:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV), SMALL CELL VARIANT.

Note: Immunohistochemical staining for primitive neuroectodermal differentiation (synaptophysin, neurofilaments) is negative.

E. PERMANENT WHITE MATTER, REMOVAL:
-- CEREBRAL CORTEX AND WHITE MATTER DEMONSTRATING FOCAL HYPERCELLULARITY, CONSISTENT WITH INFILTRATING GLIOMA.

One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents [REDACTED] have not been cleared or approved by the U.S. Food and Drug Administration. These assays were developed and their performance characteristics determined by the Department of Pathology at [REDACTED]. The assays were performed with appropriate positive and negative controls.

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A. Touch Imprint and Microscopic: Hypercellular tissue. No definite neoplasm identified.
B. Touch Imprint and Microscopic: High Grade glial neoplasm.

Clinical History:

Right occipital neoplasm

Specimens Submitted As:

A: RIGHT OCCIPITAL NEOPLASM
B: R OCCIPITAL NEOPLASM
C: 2 PERM CORE
D: 3 PERM EDGE

[page 2 of 2]
E: PERM WHITE MATTER

TCGA-19-1789

Gross Description:

A: Received fresh, for intraoperative consultation, labelled with the patient's name, number and "1", are multiple irregular fragments of tan-pink, soft tissue, 1.4 x 0.6 x 0.6 cm in aggregate. Representative sections are submitted in cassette A1 for frozen section analysis and the remainder of the specimen is submitted in toto in cassette A2.

B: Received fresh, for intraoperative consultation, labelled with patient's name and number, are multiple irregular fragments of tan-pink neural tissue, 0.6 x 0.4 x 0.3 cm in aggregate. Representative sections are submitted in cassette B1 for frozen section and permanent analysis and the remainder of the specimen is submitted entirely in cassette B2.

C: Received fresh, post fixed in formalin, labeled with the patient's name, number, and "2", are two light tan to white-tan irregular to wedge-shaped soft tissue fragments measuring 0.9 x 0.7 x 0.7 cm and 1.4 x 1.1 x 0.75 cm. Both fragments are bisected. On section, the tissue is light tan throughout. Submitted entirely in two cassettes.

D: Received fresh, post fixed in formalin, labeled with the patient's name, number, and "3", are six light tan to brown irregular to wedge-shaped soft tissue fragments ranging from 1 x 0.5 x 0.3 cm to 2.7 x 1.5 x 0.5 cm. The two largest fragments are serially sectioned. On section, the tissue is light tan throughout. Submitted entirely in four cassettes.

E: Received fresh, post fixed in formalin, labeled with the patient's name, number, and "4", are multiple light tan to white-tan irregular to wedge-shaped soft fragments of brain ranging from flecks to 4.2 x 2.2 x 1.8 cm. One side of the largest fragment is smooth and glistening.

The two largest fragments are serially sectioned. On section, the tissue is light tan to white tan and lobulated. Submitted entirely in 14 cassettes.

Summary of cassettes

D1-D2 largest fragment

D3 2nd largest fragment

D4 remaining tissue

E1-E11 largest fragment

E12-E13 2nd largest fragment

E14 remaining tissue

Source: NCI Genomic Data Commons file 36f99755-aec8-4b64-be64-1be5f8deec4a (TCGA-19-1789.6A04F636-6851-43F5-974D-97C318E73C3A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).